Somatic mutation profile of tumor specimen MMRF_2570_1_BM_CD138pos (aliquot MMRF_2570_1_BM_CD138pos_T1_KHS5U_L12841) from MMRF case MMRF_2570, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.2 years (22,368 days).
Specimen MMRF_2570_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33bf9a3b-3dc0-4524-95e6-9e17117471bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2570_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2570_1_PB_Whole_C3_KHS5U_L12842; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6df172ea-430c-403e-bbf2-520e73e7832d

The open-access MAF lists 134 somatic variants for this specimen: 54 protein-altering or splice-affecting, 11 silent, 69 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, 3'UTR 40, Intron 14, Silent 11, 5'Flank 6, 5'UTR 4, Nonsense Mutation 3, 3'Flank 3, RNA 2, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 35/140 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- AP5B1 | c.250C>T p.L84F | Missense Mutation (SNP) | VAF 48/69 reads (70%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.894); catalogued as rs1320402249; called by muse, mutect2, varscan2
- CEMP1 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.068); catalogued as rs1250207849; called by muse, mutect2, varscan2
- EFS | c.1291G>A p.G431R | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs780224177; called by muse, mutect2, varscan2
- GAL3ST3 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745551285, COSV61749016, COSV61749254; called by muse, mutect2, varscan2
- IGHJ4 | c.25A>G p.T9A | Missense Mutation (SNP) | VAF 32/50 reads (64%) | PolyPhen benign (0.143); catalogued as rs371354427; called by muse, varscan2
- IGHV2-70 | c.48G>A p.W16* | Nonsense Mutation (SNP) | VAF 40/52 reads (77%) | catalogued as rs375927713; called by muse, varscan2
- IGLL5 | c.110G>C p.G37A | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.386); catalogued as rs574663447; called by muse, mutect2, varscan2
- IGLV3-1 | c.100G>T p.G34* | Nonsense Mutation (SNP) | VAF 84/172 reads (49%) | catalogued as rs145228815; called by muse, mutect2, varscan2
- IGLV3-1 | c.320A>C p.Q107P | Missense Mutation (SNP) | VAF 79/187 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as rs192317432; called by muse, varscan2
- MTA2 | c.1855G>C p.A619P | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.094); catalogued as rs753647576; called by muse, mutect2, varscan2
- MXD3 | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 61/517 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV57463408; called by muse, mutect2, varscan2
- MYC | c.18C>G p.S6R (on ENST00000377970; = p.S21R on NM_002467.6) | Missense Mutation (SNP) | VAF 150/339 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.42); catalogued as COSV52367888, COSV52373284; called by muse, mutect2, varscan2
- OCRL | c.1598T>C p.I533T | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.329); catalogued as CM011449, CM129475; called by muse, mutect2
- PLG | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs371746732, COSV51981567; called by muse, mutect2, varscan2
- SHANK1 | c.5971C>T p.R1991W | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs200577881; called by muse, mutect2, varscan2
- TRIB2 | c.856C>T p.R286* | Nonsense Mutation (SNP) | VAF 95/249 reads (38%) | catalogued as rs1327493898, COSV50227073; called by muse, mutect2, varscan2
- TTN | c.41560G>A p.A13854T (on ENST00000591111; = p.A6430T on NM_003319.4) | Missense Mutation (SNP) | VAF 60/145 reads (41%) | PolyPhen benign (0); catalogued as rs537428006; ClinVar: uncertain significance / benign / likely benign; called by muse, mutect2, varscan2
- ZMAT1 | c.1301G>A p.R434K | Missense Mutation (SNP) | VAF 59/273 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV65657616; called by muse, mutect2, varscan2
- ABCB11 | c.1538C>T p.A513V | Missense Mutation (SNP) | VAF 61/135 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- BRPF1 | c.819T>G p.D273E | Missense Mutation (SNP) | VAF 116/190 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BRPF1 | c.821C>A p.A274D | Missense Mutation (SNP) | VAF 114/187 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CBX8 | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 75/187 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- CUBN | c.9423A>C p.K3141N | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- CYLD | c.2108+1G>A p.X703_splice | Splice Site (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- DHX36 | c.1963C>G p.L655V | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- DIP2C | c.2637G>T p.L879F | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- DNAH5 | c.2901G>T p.M967I | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- EML1 | c.1361C>T p.A454V | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- GJA3 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- GPR4 | c.571C>A p.L191I | Missense Mutation (SNP) | VAF 29/242 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- H1-5 | c.189_203del p.A64_A68del | In Frame Del (DEL) | VAF 65/171 reads (38%) | called by mutect2, pindel, varscan2
- IGHV2-70D | c.234A>T p.K78N | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.019); called by muse, varscan2
- IGHV2-70D | c.121T>G p.C41G | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- IGSF10 | c.4646C>T p.S1549F | Missense Mutation (SNP) | VAF 137/423 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KLHL6 | c.206A>G p.N69S | Missense Mutation (SNP) | VAF 106/198 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.098); called by muse, varscan2
- LARGE2 | c.626A>G p.D209G | Missense Mutation (SNP) | VAF 5/137 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- MTTP | c.1303C>A p.L435I | Missense Mutation (SNP) | VAF 8/211 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.434); called by muse, mutect2
- NCBP1 | c.91T>A p.L31M | Missense Mutation (SNP) | VAF 15/262 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NLRP8 | c.1879A>C p.N627H | Missense Mutation (SNP) | VAF 135/218 reads (62%) | SIFT tolerated (0.17); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- PALLD | c.1702A>G p.I568V | Missense Mutation (SNP) | VAF 61/157 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- PEX11G | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2
- POLR1G | c.712A>G p.T238A | Missense Mutation (SNP) | VAF 7/157 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.026); called by muse, mutect2
- PRPF3 | c.1279C>G p.P427A | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- PRPS1 | c.908C>T p.T303I | Missense Mutation (SNP) | VAF 17/200 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.167); called by muse, mutect2
- RBFOX1 | c.283G>C p.A95P | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- SIX4 | c.2299G>A p.A767T | Missense Mutation (SNP) | VAF 11/289 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.432); called by muse, mutect2
- SMURF1 | c.356G>T p.C119F | Missense Mutation (SNP) | VAF 102/234 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- SPATA2L | c.77G>C p.C26S | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- TTC31 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- TUBAL3 | c.164C>A p.S55Y | Missense Mutation (SNP) | VAF 50/279 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- VWA5A | c.92C>G p.A31G | Missense Mutation (SNP) | VAF 86/268 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZMYND15 | c.2196G>T p.K732N (on ENST00000433935 / NM_001136046.3; = p.K693N on NM_032265.2) | Missense Mutation (SNP) | VAF 13/237 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); called by muse, mutect2
- ZNF541 | c.115C>A p.P39T | Missense Mutation (SNP) | VAF 55/177 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRB2 | c.4350C>T p.P1450= | Silent (SNP) | VAF 15/24 reads (63%) | catalogued as rs771576534, COSV99925854; called by muse, mutect2, varscan2
- CBLB | c.2256G>A p.E752= | Silent (SNP) | VAF 57/451 reads (13%) | called by muse, mutect2, varscan2
- CERK | c.1485C>T p.S495= | Silent (SNP) | VAF 42/95 reads (44%) | called by muse, mutect2, varscan2
- CFAP74 | c.942G>A p.E314= | Silent (SNP) | VAF 71/150 reads (47%) | called by muse, mutect2, varscan2
- IGSF22 | c.1326G>C p.L442= | Silent (SNP) | VAF 49/192 reads (26%) | called by muse, mutect2, varscan2
- KCND3 | c.303G>A p.G101= | Silent (SNP) | VAF 104/242 reads (43%) | catalogued as COSV56186898; called by muse, mutect2, varscan2
- MRM1 | c.102G>A p.E34= | Silent (SNP) | VAF 84/192 reads (44%) | called by muse, mutect2, varscan2
- NEXMIF | c.36A>C p.S12= | Silent (SNP) | VAF 119/270 reads (44%) | called by muse, mutect2, varscan2
- RNF10 | c.1545G>A p.Q515= | Silent (SNP) | VAF 10/193 reads (5%) | called by muse, mutect2
- SGSM1 | c.1800C>T p.D600= | Silent (SNP) | VAF 48/110 reads (44%) | called by muse, mutect2, varscan2
- ZNF536 | c.459G>C p.T153= | Silent (SNP) | VAF 45/374 reads (12%) | catalogued as COSV100834827, COSV62833311; called by muse, mutect2, varscan2
- ACOT9 | c.704-36G>A | Intron (SNP) | VAF 45/105 reads (43%) | catalogued as rs764741406; called by muse, mutect2, varscan2
- ADAMTS12 | c.*3361C>A | 3'UTR (SNP) | VAF 6/127 reads (5%) | called by muse, mutect2
- AL353804.4 | chrX:73825066 A>T | 5'Flank (SNP) | VAF 11/137 reads (8%) | called by muse, mutect2
- AP000769.3 | chr11:65501443 ins A | 5'Flank (INS) | VAF 40/324 reads (12%) | catalogued as rs771258158; called by mutect2, pindel, varscan2
- ARL5B | c.*5655T>G | 3'UTR (SNP) | VAF 32/79 reads (41%) | called by muse, mutect2, varscan2
- ATP2B2 | c.*2177G>A | 3'UTR (SNP) | VAF 17/155 reads (11%) | called by muse, mutect2, varscan2
- B3GALT5-AS1 | chr21:39597994 G>A | 3'Flank (SNP) | VAF 9/197 reads (5%) | called by muse, mutect2
- B3GALT5-AS1 | n.460C>T | RNA (SNP) | VAF 13/252 reads (5%) | called by muse, mutect2
- BCL7A | chr12:122021241 A>C | 5'Flank (SNP) | VAF 49/126 reads (39%) | called by muse, mutect2, varscan2
- BMP6 | c.*1335_*1337del | 3'UTR (DEL) | VAF 8/80 reads (10%) | called by mutect2, pindel
- BRWD1 | chr21:39313963 C>T | 5'Flank (SNP) | VAF 19/35 reads (54%) | called by muse, mutect2, varscan2
- BTBD7 | c.*1900A>G | 3'UTR (SNP) | VAF 22/113 reads (19%) | called by muse, mutect2, varscan2
- CCDC148 | c.-311G>C | 5'UTR (SNP) | VAF 42/80 reads (53%) | called by muse, mutect2, varscan2
- CUL4B | chrX:120524604 C>G | 3'Flank (SNP) | VAF 18/48 reads (38%) | called by muse, mutect2, varscan2
- CYB5RL | chr1:54195688 C>T | 5'Flank (SNP) | VAF 3/48 reads (6%) | catalogued as rs936819393; called by muse, mutect2
- DMD | c.*1516C>T | 3'UTR (SNP) | VAF 27/72 reads (38%) | called by muse, mutect2, varscan2
- DNAJB14 | c.*2240dup | 3'UTR (INS) | VAF 26/70 reads (37%) | called by mutect2, varscan2
- EPN2 | c.*1498del | 3'UTR (DEL) | VAF 25/113 reads (22%) | called by mutect2, pindel, varscan2
- ERBB4 | c.*6719G>A | 3'UTR (SNP) | VAF 5/90 reads (6%) | called by muse, mutect2
- EYA1 | c.1141-8203A>C | Intron (SNP) | VAF 45/111 reads (41%) | called by muse, mutect2, varscan2
- FBXO33 | c.-291C>G | 5'UTR (SNP) | VAF 38/85 reads (45%) | called by muse, mutect2, varscan2
- FLRT2 | c.*1460G>A | 3'UTR (SNP) | VAF 8/76 reads (11%) | called by muse, mutect2
- GABRG1 | c.*3758C>T | 3'UTR (SNP) | VAF 34/81 reads (42%) | called by muse, mutect2, varscan2
- GADD45B | c.45-11C>G | Intron (SNP) | VAF 60/108 reads (56%) | called by muse, mutect2, varscan2
- GALP | c.*109A>T | 3'UTR (SNP) | VAF 41/64 reads (64%) | called by muse, mutect2, varscan2
- GCLM | c.*800G>A | 3'UTR (SNP) | VAF 31/71 reads (44%) | called by muse, mutect2, varscan2
- GPR17 | c.*15C>T | 3'UTR (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- GRAMD1B | c.*914C>T | 3'UTR (SNP) | VAF 46/136 reads (34%) | called by muse, mutect2, varscan2
- GRIA3 | c.268+16713G>A | Intron (SNP) | VAF 22/62 reads (35%) | catalogued as rs942422932; called by muse, mutect2, varscan2
- IFNW1 | c.-168C>A | 5'UTR (SNP) | VAF 33/164 reads (20%) | catalogued as COSV66522446; called by muse, mutect2, varscan2
- INS-IGF2 | c.*46+413G>A | Intron (SNP) | VAF 72/240 reads (30%) | catalogued as rs1197596027; called by muse, mutect2, varscan2
- JADE1 | c.1503+1367G>T | Intron (SNP) | VAF 37/80 reads (46%) | called by muse, mutect2, varscan2
- KCNH5 | c.1369+135dup | Intron (INS) | VAF 18/34 reads (53%) | catalogued as rs1163899921; called by mutect2, varscan2
- LARP6 | c.*1933G>A | 3'UTR (SNP) | VAF 60/155 reads (39%) | called by muse, mutect2, varscan2
- LYNX1 | c.*2720G>A | 3'UTR (SNP) | VAF 15/150 reads (10%) | called by muse, mutect2, varscan2
- LYPD6 | c.*1601C>T | 3'UTR (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2, varscan2
- MAP3K2 | c.*5388A>G | 3'UTR (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- MGAT4C | c.*284A>C | 3'UTR (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- MPPED2 | c.*1164A>G | 3'UTR (SNP) | VAF 17/64 reads (27%) | called by muse, mutect2, varscan2
- MS4A7 | c.283-71G>T | Intron (SNP) | VAF 52/194 reads (27%) | called by muse, mutect2, varscan2
- MSANTD2 | c.511-1011G>T | Intron (SNP) | VAF 56/178 reads (31%) | called by muse, mutect2, varscan2
- NFAT5 | c.1504-60T>A | Intron (SNP) | VAF 12/17 reads (71%) | called by muse, mutect2, varscan2
- NFIB | c.*1420T>G | 3'UTR (SNP) | VAF 63/126 reads (50%) | called by muse, mutect2, varscan2
- NRXN1 | c.*191A>C | 3'UTR (SNP) | VAF 20/47 reads (43%) | catalogued as rs1254825415; called by muse, mutect2, varscan2
- OSBPL8 | c.*999A>C | 3'UTR (SNP) | VAF 26/70 reads (37%) | called by muse, mutect2, varscan2
- PANK3 | c.*1944C>T | 3'UTR (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- PAPOLA | c.*743T>C | 3'UTR (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2, varscan2
- PARVA | c.*2229A>T | 3'UTR (SNP) | VAF 15/67 reads (22%) | called by muse, mutect2, varscan2
- PAX1 | c.*11C>T | 3'UTR (SNP) | VAF 83/477 reads (17%) | catalogued as rs950563500; called by muse, mutect2, varscan2
- PCDH17 | c.*216A>T | 3'UTR (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- PCGF5 | c.*916G>A | 3'UTR (SNP) | VAF 34/86 reads (40%) | called by muse, mutect2, varscan2
- PPP6C | c.76-732A>G | Intron (SNP) | VAF 31/600 reads (5%) | called by muse, mutect2
- RAPGEF5 | c.*2216C>T | 3'UTR (SNP) | VAF 40/89 reads (45%) | called by muse, mutect2, varscan2
- RASGRP1 | c.1721-232G>A | Intron (SNP) | VAF 6/128 reads (5%) | called by muse, mutect2
- REXO5 | c.*90G>T | 3'UTR (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2, varscan2
- RGS7BP | c.*2867T>G | 3'UTR (SNP) | VAF 55/98 reads (56%) | called by muse, mutect2, varscan2
- RINT1 | chr7:105532178 T>G | 5'Flank (SNP) | VAF 42/92 reads (46%) | called by muse, mutect2, varscan2
- RPL21 | c.130-75T>C | Intron (SNP) | VAF 26/56 reads (46%) | called by muse, mutect2, varscan2
- SLC49A4 | c.*829T>C | 3'UTR (SNP) | VAF 35/106 reads (33%) | catalogued as rs1411029944; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.-135G>A | 5'UTR (SNP) | VAF 11/81 reads (14%) | called by muse, mutect2, varscan2
- SYT15 | c.*528C>G | 3'UTR (SNP) | VAF 9/35 reads (26%) | called by mutect2, varscan2
- SYTL5 | c.*1785C>T | 3'UTR (SNP) | VAF 8/71 reads (11%) | catalogued as rs1024205209; called by muse, mutect2, varscan2
- TMEM151B | c.*1279G>C | 3'UTR (SNP) | VAF 39/322 reads (12%) | called by muse, mutect2, varscan2
- TNS1 | c.96+7144C>T | Intron (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- TP53I11 | c.*1741G>C | 3'UTR (SNP) | VAF 18/171 reads (11%) | called by muse, mutect2, varscan2
- TSBP1-AS1 | n.97C>T | RNA (SNP) | VAF 5/62 reads (8%) | called by muse, mutect2
- WAPL | c.*333G>A | 3'UTR (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2
- ZNF165 | chr6:28091343 C>T | 3'Flank (SNP) | VAF 31/159 reads (19%) | catalogued as rs762597488; called by muse, mutect2, varscan2
- ZNF621 | c.*4377G>T | 3'UTR (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
